Gene-level copy-number profile of tumor specimen TCGA-AO-A03M-01B from TCGA case TCGA-AO-A03M, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 29.1 years (10,616 days).
Specimen TCGA-AO-A03M-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1d26df40-c4fd-4609-8f7d-a7ad6c39ea1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A03M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/625b8b17-22c0-4abf-baf6-e1bd0aecbfaf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 8,042; copy number 2: 46,679; copy number 3: 3,248; copy number 4: 1,006; copy number 5: 305; copy number 6: 40; copy number 7: 178; copy number 8: 61; copy number 9: 13; copy number 10: 24; copy number 13: 6; copy number 15: 45; copy number 16: 14; copy number 19: 3; copy number 20: 45; copy number 24: 26; copy number 26: 14; copy number 27: 57; copy number 31: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A03M-01B-11D-A10L-01): tumor purity 0.31, ploidy 3.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:57,946,074–58,438,364, 6 genes (within-gene range 0–2): LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 832 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,623,806–2,245,605, 1 gene, copy number 7 (within-gene range 2–7): GMDS.
- chr7:86,216,785–86,217,733, 1 gene, copy number 5: SOCS5P1.
- chr17:28,648,346–29,057,216, 41 genes, copy number 7 (within-gene range 2–7): SDF2, RPS12P28, SUPT6H, AC010761.3, PROCA1, RAB34, RPL23A, SNORD42B, AC010761.1, SNORD4A, SNORD42A, SNORD4B, TLCD1, NEK8, AC010761.6, AC010761.2, TRAF4, AC010761.4, AC010761.5, FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4.
- chr17:75,318,076–75,979,177, 37 genes, copy number 6 (within-gene range 3–6): GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4.
- chr17:75,979,240–76,000,586, 1 gene, copy number 6 (within-gene range 2–6): TEN1.
- chr20:87,250–17,609,919, 325 genes, copy number 5–24 (within-gene range 1–24) (broad region; genes not listed).
- chr20:36,890,229–38,772,520, 60 genes, copy number 19–27 (within-gene range 1–27): SAMHD1, RBL1, RPS3AP3, RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2, GHRH, MANBAL, AL034422.1, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173.
- chr20:42,968,743–51,131,667, 256 genes, copy number 5–16 (broad region; genes not listed).
- chr20:51,596,514–52,204,308, 9 genes, copy number 8 (within-gene range 4–8): ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.
- chr20:52,972,358–53,495,330, 5 genes, copy number 7 (within-gene range 3–7): TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2.
- chr20:53,544,615–56,005,519, 24 genes, copy number 7–31: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4.
- chr20:56,688,401–57,712,780, 28 genes, copy number 7: RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA.
- chr20:62,640,719–63,378,401, 44 genes, copy number 5: AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.6, AL096828.2, AL096828.5, AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1.

Autosomal genes at a single copy (total copy number 1): 8,042. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
